Somatic mutation profile of tumor specimen ec9afcc4-ccf7-4226-b0e8-d6897d (aliquot ec9afcc4-ccf7-4226-b0e8-d6897d_D6) from CPTAC case 09CO005, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen ec9afcc4-ccf7-4226-b0e8-d6897d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bfbfef6-d61d-4d55-9f82-31107920b396.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 04a00ed3-7f0c-4ddf-9de5-ec7916 (Blood Derived Normal), aliquot 04a00ed3-7f0c-4ddf-9de5-ec7916_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb1c7b36-23f8-49f2-b7c8-c6cbac354600

The open-access MAF lists 136 somatic variants for this specimen: 87 protein-altering or splice-affecting, 34 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 34, 3'UTR 5, Intron 4, Nonsense Mutation 4, RNA 3, Frame Shift Del 3, Splice Region 2, Splice Site 2, 5'Flank 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 158/489 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 89/294 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4196C>T p.T1399M | Missense Mutation (SNP) | VAF 101/292 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs199668464, COSV66064398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTL9 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782777098, COSV61005735; called by muse, mutect2, varscan2
- ADRA1D | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 116/534 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV104432636; called by muse, mutect2, varscan2
- AHNAK2 | c.13129C>G p.L4377V | Missense Mutation (SNP) | VAF 149/506 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV60924616; called by muse, mutect2, varscan2
- APC | c.3625G>T p.E1209* | Nonsense Mutation (SNP) | VAF 174/510 reads (34%) | catalogued as CD011096, COSV57327136; called by mutect2, varscan2
- APC | c.4308del p.S1436Rfs*37 | Frame Shift Del (DEL) | VAF 77/261 reads (30%) | catalogued as CD084027, COSV57331668; called by mutect2, pindel, varscan2
- ATG4A | c.1070C>A p.S357* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | catalogued as COSV100565279; called by muse, mutect2, varscan2
- C17orf80 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141607167; called by muse, mutect2, varscan2
- CALD1 | c.1579G>A p.A527T (on ENST00000361675 / NM_033138.4; = p.A272T on NM_004342.7) | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs762582417, COSV62645134, COSV99054747; called by muse, mutect2, varscan2
- CD5L | c.57G>A p.A19= | Splice Region (SNP) | VAF 50/157 reads (32%) | catalogued as rs143489369; called by muse, mutect2, varscan2
- CD96 | c.1499C>T p.T500M (on ENST00000283285 / NM_198196.3; = p.T484M on NM_005816.5) | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs140955483; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH4 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs149315148; called by muse, mutect2, varscan2
- CHD4 | c.2398C>T p.R800C (on ENST00000357008 / NM_001363606.2; = p.R813C on NM_001273.5) | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894214; called by muse, mutect2, varscan2
- CILP2 | c.3443G>A p.R1148H | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1032515186, COSV52272212; called by muse, mutect2, varscan2
- COL11A1 | c.5089A>G p.T1697A | Missense Mutation (SNP) | VAF 168/478 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62177763; called by muse, mutect2, varscan2
- COL7A1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 114/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1189942401, COSV60393382; called by muse, mutect2, varscan2
- DNAAF1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 166/501 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs372901697; called by muse, mutect2, varscan2
- DSCAML1 | c.4796C>T p.T1599M (on ENST00000321322; = p.T1539M on NM_020693.4) | Missense Mutation (SNP) | VAF 122/419 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.947); catalogued as rs759898702, COSV58401421; called by muse, mutect2, varscan2
- ELAVL2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs771776728, COSV56363200; called by muse, mutect2, varscan2
- ELOA2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 179/591 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55296134; called by muse, mutect2, varscan2
- EP300 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 201/576 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99606957; called by muse, mutect2, varscan2
- EXTL3 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 267/751 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as rs546457214; called by muse, mutect2, varscan2
- HMCN2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996895499; called by muse, mutect2, varscan2
- IFNG | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757239347, COSV57490720; called by muse, mutect2, varscan2
- ITGAD | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs144853512; called by muse, mutect2, varscan2
- KRT85 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 223/630 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs147392729; called by muse, mutect2, varscan2
- LOXL2 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.426); catalogued as rs376680910, COSV66692764; called by muse, mutect2, varscan2
- MAFG | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as rs1051803653, COSV60815721; called by muse, mutect2, varscan2
- MROH5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.927); catalogued as rs566254404; called by muse, varscan2
- MYO18B | c.7457C>T p.S2486L | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs202052336, COSV100123745; called by muse, mutect2, varscan2
- NHSL2 | c.1667C>T p.T556M (on ENST00000510661; = p.T922M on NM_001013627.2) | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs752726540, COSV65453957; called by muse, mutect2, varscan2
- NPHP4 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199645515; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB3 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 171/449 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV50583416; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | catalogued as rs752653446, COSV99342923; called by mutect2, pindel
- PRDM16 | c.2534C>A p.A845E | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as COSV54599338; called by muse, mutect2, varscan2
- PRR30 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs745398301; called by muse, mutect2, varscan2
- RANGAP1 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); catalogued as rs1009104600; called by muse, mutect2, varscan2
- RP1L1 | c.3647C>T p.P1216L | Missense Mutation (SNP) | VAF 287/885 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1318036737; called by muse, mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 222/571 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- SLC25A18 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs140174333; called by muse, mutect2, varscan2
- SMAD2 | c.1314T>G p.I438M | Missense Mutation (SNP) | VAF 120/433 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV51004757; called by muse, mutect2, varscan2
- SMAD4 | c.1019A>C p.K340T | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61695242; called by muse, mutect2, varscan2
- SPARC | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.327); catalogued as rs201856432; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 46/137 reads (34%) | PolyPhen benign (0.022); catalogued as rs1000986608, COSV52535730; called by muse, mutect2, varscan2
- SYNPO | c.766C>T p.R256W (on ENST00000394243 / NM_001166208.2; = p.R12W on NM_007286.6) | Missense Mutation (SNP) | VAF 188/600 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1168499497; called by muse, mutect2, varscan2
- TAF6L | c.1840T>C p.S614P | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as rs759922469; called by muse, mutect2, varscan2
- TENM1 | c.7936G>A p.V2646M | Missense Mutation (SNP) | VAF 93/352 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773983922; called by muse, mutect2, varscan2
- TNC | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 152/442 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs780074979, COSV60783763; called by muse, mutect2, varscan2
- ZNF304 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 145/407 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs762038911, COSV56585868; called by muse, mutect2, varscan2
- ZNF628 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs780436601, COSV52698512; called by muse, mutect2
- ZNF777 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 190/640 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); catalogued as rs757271805; called by muse, mutect2, varscan2
- ZNF831 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs764686333; called by muse, mutect2, varscan2
- ABCA1 | c.4483G>A p.D1495N | Missense Mutation (SNP) | VAF 136/475 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ACSM1 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBS12 | c.1637G>T p.C546F | Missense Mutation (SNP) | VAF 183/581 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIC2 | c.561A>C p.L187F | Missense Mutation (SNP) | VAF 126/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK11 | c.5322del p.F1774Lfs*24 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- EGR4 | c.779C>A p.A260E (on ENST00000545030; = p.A157E on NM_001965.4) | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EZH1 | c.1480A>T p.K494* | Nonsense Mutation (SNP) | VAF 67/196 reads (34%) | called by muse, mutect2, varscan2
- FCGR2C | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 217/608 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FXR1 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GLI2 | c.2630C>T p.A877V (on ENST00000361492 / NM_001374353.1; = p.A894V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA1 | c.2249C>T p.T750I | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IKBKE | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IKBKG | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- LDOC1 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 157/442 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAN2B2 | c.2565G>T p.G855= | Splice Region (SNP) | VAF 55/140 reads (39%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2986G>T p.E996* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- MBTD1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MEGF8 | c.7955_7957del p.F2652del (on ENST00000251268 / NM_001271938.2; = p.F2585del on NM_001410.3) | In Frame Del (DEL) | VAF 87/323 reads (27%) | called by pindel, varscan2
- NOTCH3 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- PADI4 | c.1724A>G p.E575G | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRPF8 | c.3095G>T p.R1032I | Missense Mutation (SNP) | VAF 133/331 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRRT4 | c.161T>G p.L54R | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX7 | c.2567C>A p.T856K (on ENST00000559447 / NM_001368074.1; = p.T953K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RFX8 | c.584T>A p.L195H (on ENST00000646446; = p.L124H on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- RTL8B | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SCN3A | c.2236T>C p.W746R | Missense Mutation (SNP) | VAF 164/513 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFXN2 | c.771+1G>T p.X257_splice | Splice Site (SNP) | VAF 76/205 reads (37%) | called by muse, mutect2, varscan2
- SLAIN1 | c.1058A>C p.Q353P (on ENST00000466548; = p.Q90P on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); called by muse, mutect2
- TCF7L2 | c.256+1G>A p.X86_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TMEM168 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TRIM42 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by mutect2, varscan2
- VPS41 | c.1454G>C p.G485A | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WFS1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 158/519 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ADAMTS2 | c.2052C>T p.D684= | Silent (SNP) | VAF 155/494 reads (31%) | catalogued as rs370799965, COSV52364463; called by muse, mutect2, varscan2
- ADRB2 | c.375C>T p.C125= | Silent (SNP) | VAF 237/807 reads (29%) | catalogued as rs879105081; called by muse, mutect2, varscan2
- ATG2A | c.4278C>T p.L1426= | Silent (SNP) | VAF 77/236 reads (33%) | catalogued as rs375306816; called by muse, mutect2, varscan2
- BSN | c.9219C>T p.N3073= | Silent (SNP) | VAF 87/301 reads (29%) | catalogued as rs764944766; called by muse, mutect2, varscan2
- CACNA2D4 | c.981T>C p.I327= | Silent (SNP) | VAF 99/261 reads (38%) | called by muse, mutect2, varscan2
- CCDC166 | c.117G>A p.A39= | Silent (SNP) | VAF 105/284 reads (37%) | catalogued as COSV72638851; called by muse, mutect2, varscan2
- CCDC40 | c.1644C>T p.N548= | Silent (SNP) | VAF 245/703 reads (35%) | catalogued as rs368624849; called by muse, mutect2, varscan2
- CHD5 | c.4686G>A p.P1562= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs751701713; called by muse, mutect2, varscan2
- CROCC | c.4941C>T p.S1647= | Silent (SNP) | VAF 93/300 reads (31%) | catalogued as rs762582526; called by muse, mutect2, varscan2
- CST1 | c.135G>A p.Q45= | Silent (SNP) | VAF 166/409 reads (41%) | catalogued as rs1322447211; called by muse, mutect2, varscan2
- DCAF4L2 | c.324G>A p.T108= | Silent (SNP) | VAF 141/434 reads (32%) | catalogued as rs866937133, COSV60481476, COSV60482877; called by muse, mutect2, varscan2
- FLNC | c.6789C>T p.A2263= | Silent (SNP) | VAF 268/738 reads (36%) | catalogued as rs761059390; called by muse, mutect2, varscan2
- FLT4 | c.3144C>T p.S1048= | Silent (SNP) | VAF 142/473 reads (30%) | catalogued as rs573813758, COSV56098300; called by muse, mutect2, varscan2
- GKN1 | c.402C>T p.F134= | Silent (SNP) | VAF 87/275 reads (32%) | catalogued as rs202096982, COSV65006288; called by muse, mutect2, varscan2
- GSG1L | c.711G>A p.T237= (on ENST00000447459 / NM_001109763.2; = p.T82= on NM_144675.2) | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs144726696; called by muse, mutect2, varscan2
- HHIPL1 | c.1098C>A p.R366= | Silent (SNP) | VAF 46/156 reads (29%) | called by muse, mutect2, varscan2
- HOMER2 | c.210G>A p.T70= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs139619821, COSV58488227; called by muse, mutect2, varscan2
- KCNJ4 | c.288G>A p.A96= | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as rs764694400; called by muse, mutect2, varscan2
- KMT2B | c.7248C>T p.F2416= | Silent (SNP) | VAF 92/280 reads (33%) | catalogued as rs761988231; called by muse, mutect2, varscan2
- LVRN | c.402G>A p.T134= | Silent (SNP) | VAF 192/604 reads (32%) | called by muse, mutect2, varscan2
- MMRN1 | c.2364T>C p.T788= | Silent (SNP) | VAF 63/220 reads (29%) | called by muse, mutect2, varscan2
- MTM1 | c.1146T>A p.T382= | Silent (SNP) | VAF 160/528 reads (30%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1233C>T p.S411= | Silent (SNP) | VAF 182/554 reads (33%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1707C>T p.N569= | Silent (SNP) | VAF 269/1082 reads (25%) | catalogued as rs200168689, COSV50565563; called by muse, mutect2, varscan2
- PDHA2 | c.93C>T p.D31= | Silent (SNP) | VAF 151/457 reads (33%) | catalogued as rs143281239, COSV54779791; called by muse, mutect2, varscan2
- PRPH2 | c.507C>T p.N169= | Silent (SNP) | VAF 220/666 reads (33%) | catalogued as rs143096101, CD033226; called by muse, mutect2, varscan2
- ROR2 | c.2082C>T p.C694= | Silent (SNP) | VAF 295/959 reads (31%) | catalogued as rs773479092, COSV65221026; called by muse, mutect2, varscan2
- RTL1 | c.1428G>A p.T476= | Silent (SNP) | VAF 107/343 reads (31%) | catalogued as COSV66016381; called by muse, mutect2, varscan2
- SLC44A1 | c.1746C>T p.V582= | Silent (SNP) | VAF 138/493 reads (28%) | catalogued as rs145930596, COSV100570300; called by muse, mutect2, varscan2
- TBCE | c.627G>C p.L209= (on ENST00000366601; = p.L272= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/309 reads (25%) | called by muse, mutect2, varscan2
- TM6SF2 | c.625A>C p.R209= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV66984916; called by muse, mutect2, varscan2
- TRIML1 | c.1299G>A p.P433= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs377585886; called by muse, mutect2, varscan2
- UGT3A1 | c.1512G>T p.G504= | Silent (SNP) | VAF 70/225 reads (31%) | catalogued as COSV57096923; called by muse, mutect2, varscan2
- VWA1 | c.798G>A p.T266= | Silent (SNP) | VAF 66/204 reads (32%) | catalogued as COSV58600051; called by muse, mutect2, varscan2
- CBWD2 | c.154+1003C>T | Intron (SNP) | VAF 56/200 reads (28%) | catalogued as rs1386163216; called by muse, mutect2, varscan2
- CEP41 | c.*3388A>G | 3'UTR (SNP) | VAF 117/396 reads (30%) | called by muse, mutect2, varscan2
- FBLN2 | c.*198C>A | 3'UTR (SNP) | VAF 4/42 reads (10%) | catalogued as rs937960283; called by muse, mutect2
- HPD | c.-14G>C | 5'UTR (SNP) | VAF 144/438 reads (33%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1131C>T | RNA (SNP) | VAF 77/307 reads (25%) | called by muse, mutect2, varscan2
- KLHL4 | c.*2829C>T | 3'UTR (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- MCF2 | c.*77G>C | 3'UTR (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- MIR137 | n.78G>C | RNA (SNP) | VAF 77/209 reads (37%) | called by muse, mutect2, varscan2
- NEB | c.18826-3056T>C | Intron (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- PIPSL | n.427C>T | RNA (SNP) | VAF 141/521 reads (27%) | catalogued as rs1348324190; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159062 G>A | 5'Flank (SNP) | VAF 55/181 reads (30%) | catalogued as rs77202604; called by muse, mutect2, varscan2
- SLC4A11 | chr20:3238058 C>T | 5'Flank (SNP) | VAF 67/109 reads (61%) | called by muse, mutect2, varscan2
- SMARCB1 | c.363-2180T>A | Intron (SNP) | VAF 179/551 reads (32%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-251G>T | Intron (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- XIAP | c.*3516G>A | 3'UTR (SNP) | VAF 14/78 reads (18%) | catalogued as rs1194178245; called by muse, mutect2, varscan2
